Surgical pathology report (de-identified scan), TCGA case TCGA-HU-8238, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-8238-01A (Primary Tumor).

[page 1 of 3]
CLINICAL DIAGNOSIS:

AGC, Borrmann IV, angle, adenocarcinoma, moderately differentiated

GROSS:

Specimen submitted: Subtotal gastrectomy, fresh

Measurement: Greater curvature 19.5 cm
Lesser curvature 12.0 cm
Proximal resection margin 14.0 cm
Distal resection margin 6.0 cm
Duodenum 1.3 cm

Tumor location:

Stomach: Lower 1/3 (antrum), lesser curvature
From proximal resection margin - 5.0 cm
From distal resection margin - 4.8 cm

Tumor size: 4.0 x 3.5 cm

Tumor type: AGC (Borrmann type) I + II

Gross serosal invasion: No

Gross photo: Present

Blocks

T1-6, tumor and surrounding tissue x 6

A, antral mucosa x 1

B, body mucosa x 1

P and RM, proximal resection margin x 2

D, distal resection margin x 1

LN1-2, superior gastric lymph nodes x 2

LN3-4, inferior gastric lymph nodes x 2

LN5, '1' lymph nodes x 1

LN6, '4sb' lymph nodes x 1

LN7, '5' lymph nodes x 1

LN8, '6' lymph nodes x 1

LN9, '7' lymph nodes x 1

LN10-11, '8' lymph nodes x 2

LN12, '9' lymph nodes x 1

LN13, '11p' lymph nodes x 1

LN14, '12' lymph nodes x 1

MICROSCOPIC:

Tumor type: Adenocarcinoma- tubular, moderately differentiated

- over -

[page 2 of 3]
[REDACTED]

Depth of tumor invasion:

T3: Tumor penetration of subserosal connective tissue without invasion
of visceral peritoneum or adjacent structures

Margins: Proximal resection margin (-)
Distal resection margin (-)

Lauren classification: Intestinal

Ming classification (Growth pattern): Infiltrative

Lymphoid reaction: Present

Lymphovascular invasion: Present

Venous (large vessel) invasion: Absent

Perineural invasion: Present

Lymph node metastases:

N1: Metastasis in 1-2 regional lymph nodes

number of involved nodes 1 total number of nodes 46

perinodal extension: No

Distant metastasis(M): Unknown

Pathologic stage: pT3N1Mx (AJCC [REDACTED] edition)

SPECIAL STAIN:

Cresyl Violet stain reveals many H. pylori.

[REDACTED]

Stomach, angle, scopic, adenocarcinoma

DIAGNOSIS:

Stomach, subtotal gastrectomy:

Adenocarcinoma, moderately differentiated, infiltrating
(advanced gastric cancer)

Lymph node, perigastric, subtotal gastrectomy:

Superior gastric: Metastatic carcinoma, primary in stomach (1/10)

Inferior gastric: No tumor present (0/7)

Lymph node, regional, biopsy:

- over -

[page 3 of 3]
Labeled '1': No tumor present (0/6)
Labeled '4Sb': No tumor present (0/1)
Labeled '5': No lymphoid tissue present
Labeled '6': No tumor present (0/3)
Labeled '7': No tumor present (0/4)
Labeled '8': No tumor present (0/4)
Labeled '9': No tumor present (0/2)
Labeled '11p': No tumor present (0/8)
Labeled '12': No tumor present (0/1)

Source: NCI Genomic Data Commons file 25f40aac-7a75-43fa-907b-25640ff4cb44 (TCGA-HU-8238.AF3C83FF-FEB3-44B4-BBC8-659AACE25069.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).